Somatic mutation profile of tumor specimen TCGA-13-0800-01A (aliquot TCGA-13-0800-01A-01W-0372-09) from TCGA case TCGA-13-0800, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 52.3 years (19,087 days).
Specimen TCGA-13-0800-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3c62b744-3cbd-4eeb-9f0f-2fa94de50e82.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-0800-10A (Blood Derived Normal), aliquot TCGA-13-0800-10A-01W-0371-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dcd75f8c-f9a8-4938-b8a3-96a66763062a

The open-access MAF lists 67 somatic variants for this specimen: 50 protein-altering or splice-affecting, 13 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Silent 13, Nonsense Mutation 3, Intron 2, 5'Flank 2, Frame Shift Ins 2, Frame Shift Del 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 38/205 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.395A>T p.K132M | Missense Mutation (SNP) | VAF 42/46 reads (91%) | hotspot (GDC flag); SIFT tolerated (0.05); PolyPhen possibly damaging (0.903); catalogued as rs1057519996, COSV52666637, COSV52701687, COSV52759171; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ATR | c.7133A>T p.E2378V | Missense Mutation (SNP) | VAF 88/483 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63392084; called by muse, mutect2, varscan2
- BMS1 | c.3598C>G p.R1200G | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.49); catalogued as COSV65733941, COSV65735414; called by muse, mutect2, varscan2
- BPIFB3 | c.1059_1061del p.N353del | In Frame Del (DEL) | VAF 43/254 reads (17%) | catalogued as rs1391239091; called by pindel, varscan2
- CCSER2 | c.1306C>G p.L436V | Missense Mutation (SNP) | VAF 24/292 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.073); catalogued as COSV99826357; called by muse, mutect2
- CFTR | c.323C>A p.S108Y | Missense Mutation (SNP) | VAF 42/152 reads (28%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.962); catalogued as CM950236, COSV50095732; called by muse, mutect2, varscan2
- DCT | c.194G>C p.R65P | Missense Mutation (SNP) | VAF 45/143 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0.025); catalogued as COSV65468423, COSV65470665; called by muse, mutect2, varscan2
- DMD | c.1024G>A p.D342N | Missense Mutation (SNP) | VAF 74/409 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.169); catalogued as rs758235387, COSV55899741; called by muse, mutect2, varscan2
- FBXO11 | c.2479G>C p.E827Q (on ENST00000403359 / NM_001190274.2; = p.E743Q on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/736 reads (4%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.746); catalogued as COSV99316706; called by muse, mutect2
- FKTN | c.854C>T p.A285V | Missense Mutation (SNP) | VAF 56/229 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs137951613, COSV56312063; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FRK | c.1450C>T p.R484C | Missense Mutation (SNP) | VAF 52/148 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.036); catalogued as rs762906692, COSV73384244; called by muse, mutect2, varscan2
- GLA | c.893A>T p.N298I | Missense Mutation (SNP) | VAF 16/442 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as CM972780, COSV99516552; called by muse, mutect2
- HECW1 | c.4462G>A p.A1488T | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); catalogued as rs758768640, COSV67831804; called by muse, mutect2, varscan2
- HERC2 | c.8284C>G p.R2762G | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as rs543946257, COSV55321586; called by muse, mutect2
- HJV | c.960dup p.C321Vfs*21 (on ENST00000336751 / NM_213653.4; = p.C208Vfs*21 on NM_145277.5) | Frame Shift Ins (INS) | VAF 4/32 reads (13%) | catalogued as rs782590037; called by pindel, varscan2
- HTR1F | c.309C>A p.D103E | Missense Mutation (SNP) | VAF 23/144 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60391128; called by muse, mutect2, varscan2
- LARP4 | c.1393C>T p.P465S | Missense Mutation (SNP) | VAF 66/391 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as COSV53327070; called by muse, mutect2, varscan2
- LGR5 | c.2140C>A p.P714T | Missense Mutation (SNP) | VAF 93/418 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV57007700, COSV57009735; called by muse, mutect2, varscan2
- LLGL2 | c.389C>G p.T130R | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.805); catalogued as COSV51402437; called by muse, mutect2, varscan2
- LMNA | c.628A>G p.I210V | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.53); PolyPhen benign (0.07); catalogued as COSV61542087, COSV61544011; called by muse, mutect2
- MYBPC2 | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.298); catalogued as rs866081511, COSV63099631; called by muse, mutect2, varscan2
- OR51A4 | c.649G>T p.V217L | Missense Mutation (SNP) | VAF 52/257 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV66750048; called by muse, varscan2
- PI4KB | c.500T>G p.F167C (on ENST00000368873 / NM_001369623.1; = p.F179C on NM_002651.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 69/485 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV55021246; called by muse, mutect2, varscan2
- PNPLA6 | c.1685G>A p.R562H (on ENST00000414982 / NM_001166111.2; = p.R514H on NM_006702.5) | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.565); catalogued as rs868194151, COSV55375820; called by muse, mutect2, varscan2
- PRKCE | c.675G>T p.K225N | Missense Mutation (SNP) | VAF 17/437 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0.009); catalogued as COSV100079142; called by muse, mutect2
- PRR15L | c.288C>G p.H96Q | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV56024620, COSV56024762; called by muse, mutect2, varscan2
- PTPRT | c.1097G>T p.G366V | Missense Mutation (SNP) | VAF 33/139 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV61959370, COSV62017519; called by muse, mutect2, varscan2
- RAB41 | c.97A>G p.K33E | Missense Mutation (SNP) | VAF 35/141 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52105218; called by muse, mutect2, varscan2
- RBMX | c.559A>G p.R187G | Missense Mutation (SNP) | VAF 186/376 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.143); catalogued as rs1163156727, COSV57811325; called by muse, mutect2, varscan2
- RCAN3 | c.231C>A p.D77E | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT tolerated (0.75); PolyPhen benign (0.01); catalogued as COSV100980358; called by muse, mutect2, varscan2
- RPN2 | c.1727C>T p.T576M | Missense Mutation (SNP) | VAF 26/141 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs755601800, COSV52908841; called by muse, mutect2, varscan2
- SERPINE2 | c.340G>A p.V114M | Missense Mutation (SNP) | VAF 27/233 reads (12%) | SIFT tolerated (0.51); PolyPhen benign (0.063); catalogued as rs549448679, COSV51459247; called by muse, mutect2, varscan2
- SLC25A2 | c.116C>T p.T39M | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs781985961, COSV53403577; called by muse, mutect2, varscan2
- SLC28A2 | c.375G>C p.K125N | Missense Mutation (SNP) | VAF 72/152 reads (47%) | SIFT tolerated (0.46); PolyPhen benign (0.028); catalogued as COSV61663235, COSV61663388, COSV61665215; called by muse, mutect2, varscan2
- TSPYL5 | c.1109A>C p.N370T | Missense Mutation (SNP) | VAF 79/347 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as COSV100439089; called by muse, mutect2, varscan2
- ZNF180 | c.620C>A p.S207* | Nonsense Mutation (SNP) | VAF 31/601 reads (5%) | catalogued as COSV99660040; called by muse, mutect2
- ZNF493 | c.1538C>A p.S513Y | Missense Mutation (SNP) | VAF 55/430 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.31); catalogued as COSV62752123; called by muse, mutect2, varscan2
- ZNF614 | c.1429C>T p.H477Y | Missense Mutation (SNP) | VAF 46/278 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99571909; called by muse, varscan2
- ZNF614 | c.1156C>G p.L386V | Missense Mutation (SNP) | VAF 48/370 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99571917; called by muse, mutect2
- ZNF614 | c.694C>T p.P232S | Missense Mutation (SNP) | VAF 26/162 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as COSV99571928; called by muse, varscan2
- ZNF614 | c.416C>G p.S139* | Nonsense Mutation (SNP) | VAF 25/123 reads (20%) | catalogued as COSV54548253; called by muse, mutect2, varscan2
- ZNF674 | c.726T>A p.H242Q | Missense Mutation (SNP) | VAF 36/183 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70379741; called by muse, mutect2, varscan2
- AL645922.1 | c.2890del p.E964Kfs*7 | Frame Shift Del (DEL) | VAF 22/179 reads (12%) | called by mutect2, pindel, varscan2
- CUX2 | c.1654C>A p.Q552K | Missense Mutation (SNP) | VAF 2/12 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.412); called by muse, mutect2
- KRTAP5-7 | c.473_474insGTCTGCTGCTGCAAGCC p.V159Sfs*22 | Frame Shift Ins (INS) | VAF 7/132 reads (5%) | called by muse*, mutect2
- PCDHB8 | c.37C>G p.Q13E | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- TM7SF2 | c.545G>T p.R182L | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TTN | c.36559C>A p.P12187T (on ENST00000591111; = p.P4763T on NM_003319.4) | Missense Mutation (SNP) | VAF 10/108 reads (9%) | PolyPhen benign (0.15); called by muse, mutect2
- ZBTB33 | c.380C>G p.S127* | Nonsense Mutation (SNP) | VAF 13/111 reads (12%) | called by muse, mutect2, varscan2
- ADGRE1 | c.2163G>A p.P721= | Silent (SNP) | VAF 72/424 reads (17%) | catalogued as rs150705433; called by muse, mutect2, varscan2
- AIFM1 | c.1005C>G p.P335= | Silent (SNP) | VAF 70/263 reads (27%) | catalogued as rs371944474, COSV54857610; called by muse, mutect2, varscan2
- ANKMY1 | c.1149G>A p.V383= | Silent (SNP) | VAF 24/54 reads (44%) | catalogued as COSV99802988; called by muse, mutect2, varscan2
- C19orf57 | c.51A>C p.P17= | Silent (SNP) | VAF 215/884 reads (24%) | catalogued as COSV60970220; called by muse, mutect2, varscan2
- DLEC1 | c.2430C>T p.V810= | Silent (SNP) | VAF 5/30 reads (17%) | called by muse, mutect2
- DNAH8 | c.8880T>C p.R2960= | Silent (SNP) | VAF 54/350 reads (15%) | catalogued as COSV59478633; called by muse, mutect2, varscan2
- ITGA7 | c.2787C>T p.G929= (on ENST00000555728; = p.G885= on NM_002206.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/64 reads (20%) | catalogued as rs751647692, COSV57695965, COSV57697621; called by muse, mutect2, varscan2
- NBAS | c.2514G>C p.T838= | Silent (SNP) | VAF 126/926 reads (14%) | catalogued as COSV55737106, COSV55741449; called by muse, mutect2, varscan2
- NUAK2 | c.1152C>T p.A384= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as COSV65682590; called by muse, mutect2, varscan2
- TCIRG1 | c.1329C>A p.G443= | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as COSV55837399; called by muse, mutect2, varscan2
- TGM2 | c.531C>T p.N177= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as rs1425142707, COSV63932399; called by muse, mutect2, varscan2
- TSPAN16 | c.513G>A p.T171= | Silent (SNP) | VAF 52/829 reads (6%) | catalogued as rs763399650, COSV57441977; called by muse, mutect2
- ZNF614 | c.292C>T p.L98= | Silent (SNP) | VAF 14/72 reads (19%) | catalogued as COSV99571931; called by muse, varscan2
- C1orf194 | chr1:109113638 C>A | 5'Flank (SNP) | VAF 4/24 reads (17%) | catalogued as COSV64047032; called by muse, mutect2
- MFRP | chr11:119345801 C>A | 5'Flank (SNP) | VAF 4/20 reads (20%) | catalogued as COSV100793518; called by muse, mutect2, varscan2
- SPEN | c.404+1197T>C | Intron (SNP) | VAF 62/207 reads (30%) | catalogued as rs761555839, COSV65367306; called by muse, mutect2, varscan2
- TOX2 | c.907-863G>A | Intron (SNP) | VAF 38/143 reads (27%) | catalogued as rs142800786; called by muse, mutect2, varscan2
